Somatic mutation profile of tumor specimen MP2PRT-PAVHIL-TMP1-A (aliquot MP2PRT-PAVHIL-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVHIL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,372 days).
Specimen MP2PRT-PAVHIL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d4e6ef5-7fef-43e9-bce9-089a4164973d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHIL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHIL-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7afc74b2-981e-42b5-b7c7-ee158984f283

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL5 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 137/525 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs552870097, COSV100389271, COSV57861659; called by muse, mutect2, varscan2
- CFH | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.065); catalogued as COSV100661520; called by muse, mutect2
- COL5A3 | c.3286G>A p.A1096T | Missense Mutation (SNP) | VAF 102/386 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.373); catalogued as rs763284986, COSV53406949; called by muse, mutect2, varscan2
- DAAM2 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 108/460 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); catalogued as rs375083979, COSV51303029, COSV51355669; called by muse, mutect2, varscan2
- DNAH2 | c.12076G>A p.D4026N | Missense Mutation (SNP) | VAF 133/385 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.476); catalogued as rs200760062, COSV101209082, COSV66723898; called by muse, mutect2, varscan2
- DVL1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 74/468 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs747373290, COSV66680038; called by muse, mutect2, varscan2
- EIF4G1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 94/345 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs774329173; called by muse, mutect2, varscan2
- HERC2 | c.8351G>A p.R2784H | Missense Mutation (SNP) | VAF 294/647 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs371697885; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 118/389 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCYT1B | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1258414599; called by muse, mutect2, varscan2
- SORCS1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 83/587 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV53876810; called by muse, mutect2, varscan2
- SSTR5 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 101/571 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs34803442; called by muse, mutect2, varscan2
- TBXA2R | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 24/574 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as rs773943436; called by muse, mutect2
- THSD4 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 96/387 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1047886406, COSV55980805; called by muse, varscan2
- ZNF674 | c.895C>G p.Q299E | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); catalogued as rs1262651960; called by muse, mutect2, varscan2
- ZNF862 | c.3235G>A p.D1079N | Missense Mutation (SNP) | VAF 114/726 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs928825135, COSV56222645; called by muse, mutect2
- CCDC168 | c.21118A>C p.T7040P | Missense Mutation (SNP) | VAF 52/385 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EFR3A | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- GABRD | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 45/320 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGLV4-60 | chr22:22162670 CAGTAACACTCACACA>GCGAGT | Missense Mutation (DEL) | VAF 58/83 reads (70%) | called by pindel, varscan2*
- NXPH1 | c.8C>G p.A3G | Missense Mutation (SNP) | VAF 151/449 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLIN1 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 170/576 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TLL1 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 103/328 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OR2A25 | c.621G>A p.V207= | Silent (SNP) | VAF 59/339 reads (17%) | called by muse, mutect2, varscan2
- PCDH8 | c.1911G>A p.Q637= | Silent (SNP) | VAF 119/701 reads (17%) | catalogued as rs1257213410; called by muse, mutect2, varscan2
- PIEZO2 | c.1311C>T p.N437= | Silent (SNP) | VAF 157/484 reads (32%) | catalogued as rs891413145; called by muse, mutect2, varscan2
- POLD2 | c.930C>T p.P310= | Silent (SNP) | VAF 67/526 reads (13%) | catalogued as rs1197507789; called by muse, varscan2
- RAET1G | c.978G>A p.S326= | Silent (SNP) | VAF 75/335 reads (22%) | catalogued as rs767323025; called by muse, mutect2, varscan2
- SCYL1 | c.1005C>T p.F335= | Silent (SNP) | VAF 44/323 reads (14%) | called by muse, mutect2, varscan2
- SLC36A2 | c.1176G>C p.L392= | Silent (SNP) | VAF 66/244 reads (27%) | called by muse, mutect2, varscan2
- SOWAHB | c.978C>G p.R326= | Silent (SNP) | VAF 32/666 reads (5%) | catalogued as COSV57554753; called by muse, mutect2
- TTN | c.37380C>T p.I12460= (on ENST00000591111; = p.I5036= on NM_003319.4) | Silent (SNP) | VAF 55/299 reads (18%) | catalogued as rs377445639; called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506995 ins AGGGGGGTTCTA | 3'Flank (INS) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- IGHV1-58 | chr14:106627248 ins T | 5'Flank (INS) | VAF 42/101 reads (42%) | called by mutect2, pindel*, varscan2*
- IGHV3-53 | chr14:106592675 ins TCTCTCCCA | 3'Flank (INS) | VAF 13/62 reads (21%) | called by muse*, pindel, varscan2*
